TCGA case TCGA-HM-A4S6 — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6bcf8b41-7abc-4b6f-899a-1f67b4ada765

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 51.8 years (18,903 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC pathologic T: T1b2; AJCC pathologic N: N1; AJCC pathologic M: MX; FIGO stage: Stage IIIB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph node involved site: Pelvis, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 13; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 222 days; Days to treatment end: 262 days; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 223 days; Days to treatment end: 243 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 263 days; Days to treatment end: 277 days; Treatment dose: 2,100 cGy; Treatment outcome: Complete Response; Number of fractions: 6; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.

Follow-up (14 entries)
- Day 11 (preoperative): Days to imaging: 11 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day 11 (preoperative): Days to imaging: 11 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 11 (preoperative): Days to imaging: 11 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 11 (preoperative): Days to imaging: 11 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day 11 (preoperative): Days to imaging: 11 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day 24 (preoperative): Days to imaging: 24 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day 24 (preoperative): Days to imaging: 24 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day 24 (preoperative): Days to imaging: 24 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 24 (preoperative): Days to imaging: 24 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 24 (preoperative): Days to imaging: 24 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 24 (preoperative): Days to imaging: 24 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day 38 (preoperative): ECOG performance status: 0.
- Days to follow up: 244 days; Disease response: Tumor Free.
- Days to follow up: 454 days (1.2 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 101 kg; Height: 152 cm; BMI: 43.7.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Former User; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: No.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 10; Tobacco smoking quit year: 1995; Age at onset: 14.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HM-A4S6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 390 mg.
  Slide TCGA-HM-A4S6-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-HM-A4S6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HM-A4S6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-HM-A4S6-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 430 mg.
  Slide TCGA-HM-A4S6-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 5; Pregnancies count miscarriage: 1; Total pregnancy count: 6; Tobacco smoking history indicator: 3; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Tissue in the cervix during pelvic exam was passed ans sent for pathology; Margins involved hysterectomy: Other Location, specify; Other involved margins: Squamous cell carcinoma in situ focallly extends to the cervical cuff margin(6-9 o'clock; Lymph nodes examined: Yes; Lymphovascular invasion: Present; Corpus involvement: Absent; New tumor event diagnosis indicator: No.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator).
- Fdg or ct pet performed outcomes: Fedpet or ct results: Bladder Absent; Fedpet or ct results: Extra-Pelvic Metastatic Disease Absent; Fedpet or ct results: Parametrium Absent; Fedpet or ct results: Paraaortic Nodes Absent; Fedpet or ct results: Pelvic Nodes Absent; Fedpet or ct results: Supraclavicular Absent.
- Diagnostic ct result outcomes: Ct scan preop results: Bladder Absent; Ct scan preop results: Extra-Pelvic Metastatic Disease Absent; Ct scan preop results: Parametrium Absent; Ct scan preop results: Paraaortic Nodes Absent; Ct scan preop results: Pelvic Nodes Absent.
- Treatment, Radiation therapy info: Radiation treatment reason not completed other: Radiation currently ongoing- treatment delayed due to postoperative complication.
- Treatment, Concurrent prescription treatment info: Chemo concurrent reason not other: Concurent chemo RT Ongoing-treatment delayed due to postoperative complications.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form, Treatment, Radiation therapy info: Brachytherapy type: HDR; Radiation therapy xrt type: Imrt.
- Follow-up form, Treatment, Concurrent prescription treatment info: Chemo concurrent reason not given: Adverse event/ complications.
- Follow-up form, Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent dose: 70 mg; Chemo concurrent course: Once weekly; Chemo concurrent fractions total: 4.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 454 days; disease-specific survival: no event (censored), 454 days; disease-free interval: no event (censored), 454 days; progression-free interval: no event (censored), 454 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HM-A4S6-01A-11D-A26F-01): tumor purity 0.54, ploidy 2.11, whole-genome doublings 0.
